CGCI case HTMCP-03-06-02179 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3860f2ec-0b31-468d-a18f-1de28fb6b07e

Demographics
Sex at birth: female; Race: black or african american; Age at index: 38 years; Vital status: Dead; Days to death: 377 days (1.0 years).

Diagnoses (1)
1. Squamous cell carcinoma, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Year of diagnosis: 2014; Method of diagnosis: Biopsy; AJCC clinical T: T2b; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IIB; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 377 days (1.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 151 days; Days to treatment end: 275 days; Number of cycles: 6.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 327 days; Days to treatment end: 327 days; Number of cycles: 1.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 127 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 127 days.
- Days to follow up: 377 days (1.0 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day -3,296.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day -3,296: Risk factors: HIV/AIDS.
- Day -3,296: Comorbidities: HIV/AIDS.
- Day 0: Weight: 81.1 kg; Height: 164.5 cm; BMI: 30; CD4 count: 427; Haart treatment indicator: Yes; HIV viral load: 0; Hormonal contraceptive use: Current User; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Day 0: Nadir CD4 count: 5.
- Day 0: Pregnancy outcome: Miscarriage.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02179-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02179-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02179-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 4; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 5; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Non-Keratinizing; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2005; HIV rna load at diagnosis: 0; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, Treatment, Radiation therapy info: Radiation treatment reason not completed other: Unclear if RT prescribed.
- Follow-up form, Treatment, Concurrent prescription treatment info: Chemo concurrent reason not other: Unclear if chemo prescribed.
- Follow-up form, New tumor event 1: New tumor event type: Locoregional Recurrence; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, New tumor event 2: New tumor event type: Locoregional Recurrence; New tumor event site other: Pelvis; New tumor event surgery: No; New tumor event radiation treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Treatment type: Surgery.
- Treatments, Treatment 2: Therapy regimen: Recurrence; Chemo end reporting period: Yes; Pharmaceutical regimen: Paclitaxel + Cisplatin; Pharma adjuvant cycles count: 6.
- Treatments, Treatment 3: Therapy regimen: Progression; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Paclitaxel/carboplatin; Pharma adjuvant cycles count: 1.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02179-01A-01R-6194:
- % tumour top: 50
- % tumour bottom: 50

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02179-01A-01D-6194:
- % tumour top: 50
- % tumour bottom: 50

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementData_20170519.xlsx, for sample HTMCP-03-06-02179-10A-01D-6194:
- % tumour top: 0
- % tumour bottom: 0
